Gene-level copy-number profile of tumor specimen TCGA-D7-8570-01A from TCGA case TCGA-D7-8570, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 44.2 years (16,150 days).
Specimen TCGA-D7-8570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.40aaa2ff-f475-4fc1-b100-2edfea304627.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8570-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55dc28e8-98c5-4dcf-ba92-f5a7540274f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 9,114; copy number 2: 38,215; copy number 3: 8,963; copy number 4: 2,686; copy number 5: 482; copy number 6: 348.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8570-01A-11D-2338-01): tumor purity 0.32, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 830 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr8:24,294,069–24,912,073, 5 genes, copy number 6 (within-gene range 3–6): ADAM28, AC120193.1, ADAMDEC1, ADAM7, AC024958.1.
- chr15:97,533,738–101,933,350, 115 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,869. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
